Somatic mutation profile of tumor specimen TCGA-B0-5095-01A (aliquot TCGA-B0-5095-01A-01D-1421-08) from TCGA case TCGA-B0-5095, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 81.9 years (29,921 days).
Specimen TCGA-B0-5095-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 39c9e7e9-74a6-4525-94f4-d9b9e55cab73.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-5095-11A (Solid Tissue Normal), aliquot TCGA-B0-5095-11A-01D-1421-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/310d3c5b-f7c2-4ca8-be0e-8f912478e902

The open-access MAF lists 85 somatic variants for this specimen: 68 protein-altering or splice-affecting, 15 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 15, Frame Shift Del 7, Splice Site 3, Nonsense Mutation 2, Frame Shift Ins 2, Intron 2, In Frame Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.464-1G>C p.X155_splice | Splice Site (SNP) | VAF 19/55 reads (35%) | hotspot (GDC flag); catalogued as rs5030817, CS071276, CS941547, CS961706, COSV56542304, COSV56544494, COSV56544554, COSV56553901; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AGTPBP1 | c.1182del p.F394Lfs*13 (on ENST00000357081 / NM_001330701.2; = p.F354Lfs*13 on NM_015239.2) | Frame Shift Del (DEL) | VAF 10/74 reads (14%) | catalogued as rs1331302673; called by mutect2, pindel
- AKAP17A | c.662A>G p.Y221C | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.32); catalogued as COSV58308831; called by muse, mutect2, varscan2
- ANKRD17 | c.4310G>C p.C1437S | Missense Mutation (SNP) | VAF 52/286 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV58217364; called by muse, mutect2, varscan2
- ASB6 | c.470T>C p.L157P | Missense Mutation (SNP) | VAF 41/232 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52964623; called by muse, mutect2, varscan2
- BAP1 | c.1379C>G p.S460* | Nonsense Mutation (SNP) | VAF 18/94 reads (19%) | catalogued as COSV56231488; called by muse, mutect2, varscan2
- BMP1 | c.1050G>A p.W350* | Nonsense Mutation (SNP) | VAF 44/254 reads (17%) | catalogued as COSV60477252; called by muse, mutect2, varscan2
- C1orf112 | c.445G>C p.D149H | Missense Mutation (SNP) | VAF 48/397 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.467); catalogued as COSV53677283; called by muse, mutect2, varscan2
- CCDC105 | c.1109A>G p.E370G | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52963430; called by muse, mutect2, varscan2
- CMC1 | c.302A>G p.K101R | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV55423410; called by muse, mutect2, varscan2
- DDTL | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.003); catalogued as rs889718054, COSV53159385; called by muse, mutect2, varscan2
- DNMT1 | c.2088G>A p.M696I | Missense Mutation (SNP) | VAF 69/439 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV61577456; called by muse, mutect2, varscan2
- DUS3L | c.1684G>T p.G562C | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57831397; called by muse, mutect2
- ESRP1 | c.982G>C p.V328L | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.041); catalogued as COSV64408382; called by muse, mutect2, varscan2
- EXOC4 | c.2459A>C p.D820A | Missense Mutation (SNP) | VAF 39/178 reads (22%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.984); catalogued as COSV54088447; called by muse, mutect2, varscan2
- FANCF | c.681C>G p.H227Q | Missense Mutation (SNP) | VAF 37/193 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.107); catalogued as COSV59415824; called by muse, mutect2, varscan2
- FYN | c.1535C>A p.T512N | Missense Mutation (SNP) | VAF 76/419 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV57611160; called by muse, mutect2, varscan2
- GABRA1 | c.478C>T p.L160= | Splice Region (SNP) | VAF 37/347 reads (11%) | catalogued as rs1269683161, COSV50099849; ClinVar: likely benign; called by muse, mutect2, varscan2
- GDF9 | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51525956; called by muse, mutect2, varscan2
- GFRA3 | c.629C>T p.P210L | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.199); catalogued as COSV51228118; called by muse, mutect2, varscan2
- GUSB | c.1138G>A p.A380T | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as rs377615121, COSV59221150; called by muse, mutect2, varscan2
- ITPR2 | c.7727C>A p.T2576K | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67266490; called by muse, mutect2, varscan2
- KCNA1 | c.1158G>T p.K386N | Missense Mutation (SNP) | VAF 172/677 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66836837; called by muse, mutect2, varscan2
- KRT82 | c.1486C>T p.R496W | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.348); catalogued as rs139996519, COSV99233615; called by muse, mutect2, varscan2
- MOCOS | c.1081T>A p.S361T | Missense Mutation (SNP) | VAF 34/179 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV54341883; called by muse, mutect2, varscan2
- MOV10L1 | c.1407A>C p.Q469H | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.428); catalogued as COSV53168631; called by muse, mutect2, varscan2
- MTREX | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 16/348 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1434720071, COSV57924487; called by muse, mutect2
- MUC16 | c.20297C>T p.S6766L | Missense Mutation (SNP) | VAF 78/465 reads (17%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as rs200769888; called by muse, mutect2, varscan2
- MYL6B | c.241G>C p.D81H | Missense Mutation (SNP) | VAF 91/419 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV52878436; called by muse, mutect2, varscan2
- NCOA3 | c.3565C>G p.Q1189E | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV59066890; called by muse, mutect2, varscan2
- NEB | c.19616G>A p.R6539Q | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs779983347, COSV50857594; called by muse, mutect2
- OR2G2 | c.817C>A p.Q273K | Missense Mutation (SNP) | VAF 47/336 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.877); catalogued as COSV60739606; called by muse, mutect2, varscan2
- PDE2A | c.871C>T p.P291S | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.183); catalogued as rs1043628030, COSV57803918; called by muse, mutect2, varscan2
- PIAS1 | c.602G>A p.R201K | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51030667; called by muse, mutect2, varscan2
- PKDREJ | c.3467C>T p.T1156I | Missense Mutation (SNP) | VAF 46/273 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV53547370; called by muse, mutect2, varscan2
- PRELID1 | c.70C>A p.Q24K | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.048); catalogued as COSV57462971; called by muse, mutect2, varscan2
- PRPSAP1 | c.1003G>A p.V335M | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV53151678; called by muse, mutect2, varscan2
- PRRC2C | c.3727G>A p.E1243K (on ENST00000367742; = p.E1241K on NM_015172.4) | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV58902531; called by muse, mutect2, varscan2
- RTF2 | c.204C>A p.D68E | Missense Mutation (SNP) | VAF 66/348 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV50128055; called by muse, mutect2, varscan2
- RTL1 | c.44A>G p.H15R | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs757149750, COSV66016533; called by muse, mutect2, varscan2
- SAMD3 | c.1361A>T p.E454V | Missense Mutation (SNP) | VAF 30/151 reads (20%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.898); catalogued as COSV62384945; called by muse, mutect2, varscan2
- SLAMF7 | c.535A>G p.I179V | Missense Mutation (SNP) | VAF 24/194 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.096); catalogued as COSV63562885; called by muse, mutect2, varscan2
- SLC29A1 | c.523C>T p.P175S | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.492); catalogued as rs761450983, COSV57577590; called by muse, mutect2, varscan2
- STC2 | c.97G>T p.G33C | Missense Mutation (SNP) | VAF 52/242 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); catalogued as COSV54178746; called by muse, mutect2, varscan2
- TAF4B | c.1672G>A p.G558R | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.726); catalogued as COSV52302079; called by muse, mutect2, varscan2
- TBC1D9B | c.2120T>A p.L707Q | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62281404; called by muse, mutect2, varscan2
- TENM2 | c.7450G>A p.V2484M (on ENST00000518659 / NM_001122679.2; = p.V2245M on NM_001080428.3) | Missense Mutation (SNP) | VAF 31/210 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV69125049; called by muse, mutect2, varscan2
- THADA | c.1772G>T p.R591M | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1200495102, COSV57678680, COSV57683484; called by muse, mutect2, varscan2
- TIE1 | c.810G>C p.E270D | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV65248903; called by muse, mutect2, varscan2
- TMEM184C | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.911); catalogued as COSV56853263; called by muse, mutect2, varscan2
- UACA | c.2634A>C p.K878N | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.931); catalogued as COSV59854200; called by muse, mutect2
- UNC45B | c.1907G>C p.C636S | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.218); catalogued as rs764876939, COSV52093335; called by muse, mutect2, varscan2
- USP25 | c.1276C>G p.L426V | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.187); catalogued as COSV53482252; called by muse, mutect2, varscan2
- ZGPAT | c.1297G>C p.G433R | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as rs17855481, COSV56648989; called by mutect2, varscan2
- ZMYND8 | c.1289C>T p.P430L (on ENST00000311275 / NM_001363741.2; = p.P450L on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/149 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1168487811, COSV53684375; called by muse, mutect2
- ZNF530 | c.1210G>C p.E404Q | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.969); catalogued as COSV60531105; called by muse, mutect2, varscan2
- ZRANB1 | c.1327T>A p.C443S | Missense Mutation (SNP) | VAF 46/238 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); catalogued as COSV62841811; called by muse, mutect2, varscan2
- CAD | c.2407_2409dup p.E803dup | In Frame Ins (INS) | VAF 16/102 reads (16%) | called by mutect2, pindel, varscan2
- CUL9 | c.7139_7150+2del p.X2380_splice | Splice Site (DEL) | VAF 9/94 reads (10%) | called by mutect2, pindel
- KMT2A | c.3549dup p.I1184Yfs*28 | Frame Shift Ins (INS) | VAF 41/188 reads (22%) | called by mutect2, pindel, varscan2
- MAP1LC3B2 | c.243del p.L82Wfs*2 | Frame Shift Del (DEL) | VAF 46/185 reads (25%) | called by mutect2, pindel, varscan2
- NAA40 | c.505_506dup p.K170Rfs*5 | Frame Shift Ins (INS) | VAF 58/579 reads (10%) | called by mutect2, pindel, varscan2
- PAXBP1 | c.2639_2642del p.E880Afs*2 | Frame Shift Del (DEL) | VAF 11/63 reads (17%) | called by mutect2, pindel
- PDIA6 | c.436_437del p.Y146Qfs*9 | Frame Shift Del (DEL) | VAF 10/72 reads (14%) | called by mutect2, pindel
- PLD3 | c.609del p.K203Nfs*22 | Frame Shift Del (DEL) | VAF 8/54 reads (15%) | called by mutect2, pindel, varscan2
- RIN3 | c.367+1_367+3del p.X123_splice | Splice Site (DEL) | VAF 23/139 reads (17%) | called by mutect2, pindel, varscan2
- SLC47A2 | c.1191del p.F397Lfs*11 | Frame Shift Del (DEL) | VAF 18/90 reads (20%) | called by mutect2, pindel, varscan2
- TRIM55 | c.15_25del p.N6Ffs*10 | Frame Shift Del (DEL) | VAF 18/137 reads (13%) | called by mutect2, pindel, varscan2
- ATP8B1 | c.3267C>T p.G1089= | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as COSV52173700; called by muse, mutect2, varscan2
- C19orf47 | c.1149C>A p.V383= | Silent (SNP) | VAF 7/81 reads (9%) | catalogued as COSV63508628; called by muse, mutect2, varscan2
- CDH8 | c.1233G>T p.G411= | Silent (SNP) | VAF 11/144 reads (8%) | catalogued as COSV54854760; called by muse, mutect2
- CDKN2AIP | c.531G>C p.T177= | Silent (SNP) | VAF 25/127 reads (20%) | catalogued as COSV56626878; called by muse, mutect2, varscan2
- EAF2 | c.612C>A p.S204= | Silent (SNP) | VAF 37/204 reads (18%) | catalogued as rs749678234, COSV56543735, COSV56544499; called by muse, mutect2, varscan2
- FRMD4A | c.2130C>T p.S710= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as COSV62264969; called by muse, mutect2, varscan2
- GDPD5 | c.483G>A p.A161= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as rs373585381; called by muse, mutect2
- KIF4A | c.2607T>C p.Y869= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as rs1422808272, COSV65542099; called by muse, mutect2, varscan2
- NDC80 | c.1857C>T p.L619= | Silent (SNP) | VAF 19/153 reads (12%) | catalogued as COSV55247341; called by muse, mutect2, varscan2
- NR3C1 | c.792T>G p.V264= | Silent (SNP) | VAF 82/561 reads (15%) | catalogued as COSV51540980; called by muse, mutect2, varscan2
- OR2W3 | c.921G>A p.G307= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as rs774936311, COSV64456010; called by muse, mutect2, varscan2
- PDE1B | c.255G>A p.L85= | Silent (SNP) | VAF 38/207 reads (18%) | catalogued as COSV54490763; called by muse, mutect2, varscan2
- TM9SF3 | c.729T>A p.I243= | Silent (SNP) | VAF 25/157 reads (16%) | catalogued as COSV64456895; called by muse, mutect2, varscan2
- ZNF438 | c.1998A>G p.L666= | Silent (SNP) | VAF 57/290 reads (20%) | catalogued as COSV59193118; called by muse, mutect2, varscan2
- ZNF625 | c.822G>A p.P274= | Silent (SNP) | VAF 42/223 reads (19%) | catalogued as rs188764180, COSV63241520; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-47972T>C | Intron (SNP) | VAF 12/156 reads (8%) | catalogued as COSV67441581, COSV67442533; called by muse, mutect2
- SPTB | c.6602+1234_6602+1235insA | Intron (INS) | VAF 6/18 reads (33%) | catalogued as COSV61551926; called by mutect2, varscan2
